Gene-level copy-number profile of tumor specimen TCGA-OR-A5K0-01A from TCGA case TCGA-OR-A5K0, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 69.5 years (25,400 days).
Specimen TCGA-OR-A5K0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.07723492-863e-44a2-9b69-6385e30671c9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5K0-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b1fc6fa1-afcb-494b-9977-42979f8c6795

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 10,670; copy number 2: 45,823; copy number 3: 3,277; copy number 4: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5K0-01A-11D-A29H-01): tumor purity 1, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:45,016,399–45,306,209, 2 genes (within-gene range 0–1): ZSWIM5, OSTCP5.
- chr1:246,566,444–246,668,595, 1 gene (within-gene range 0–2): CNST.
- chr1:246,632,251–246,768,137, 5 genes (within-gene range 0–1): AL591623.2, AL591848.2, AL591848.1, SCCPDH, RPL35AP6.
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.
- chr13:114,234,887–114,337,626, 8 genes: CDC16, MIR548AR, MIR4502, AL160396.2, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr16:84,009,667–84,116,942, 5 genes (within-gene range 0–1): SLC38A8, RNA5SP432, AC040169.4, MBTPS1, AC040169.3.
- chr19:58,479,512–58,512,413, 1 gene (within-gene range 0–2): SLC27A5.
- chr19:58,500,505–58,605,223, 12 genes: AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 9,874. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
